Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A20U, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A20U-01A (Primary Tumor).

105-0-3

carcinoma, urothelial 8120/3

Site: bladder, trigone c 67.0

4/7/11 W

PATIENT HISTORY:

None given.

PRE-OP DIAGNOSIS: Bladder cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical cystectomy.

FINAL DIAGNOSIS:

PART 1:

LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF CARCINOMA IN FIVE (5) LYMPH NODES EXAMINED.

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -

NO EVIDENCE OF CARCINOMA IN TWO (2) LYMPH NODES EXAMINED.

PART 3:

RIGHT PELVIC CYST, EXCISION -

LEIOMYOMA WITH HYALINIZATION AND DEGENERATION.

PART 4:

BLADDER, UTERUS, BILATERAL FALLOPIAN TUBES AND OVARIES, RADICAL CYSTECTOMY, HYSTERECTOMY, AND BILATERAL SALPINGO-OOPHORECTOMY -

A. INVASIVE UROTHELIAL CARCINOMA (3.5 CM), HIGH GRADE (WHO/ISUP).

B. CARCINOMA INVADES THE DETRUSOR MUSCLE (INNER AND OUTER) AND PERIVESICAL FAT.

C. SURGICAL MARGINS ARE FREE OF TUMOR.

D. NO CARCINOMA IN SITU IS IDENTIFIED.

E. PERINEURAL INVASION IS IDENTIFIED.

F. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.

G. TNM PATHOLOGIC STAGING = T3a N0 MX.

H. TNM HISTOPATHOLOGIC GRADE = G3.

I. EXTENSIVE SQUAMOUS METAPLASIA WITH HYPERPLASIA AND REACTIVE ATYPIA.

J. VAGINA IS FREE OF TUMOR.

K. CERVIX SHOWS MULTIPLE NABOTHIAN CYSTS AND IS FREE OF TUMOR.

L. UTERUS SHOWS ATROPHIC ENDOMETRIUM, LEIOMYOMATA, AND IS FREE OF TUMOR.

M. FALLOPIAN TUBES AND OVARIES SHOW NO SPECIFIC PATHOLOGIC ABNORMALITY, FREE OF TUMOR.

PART 5:

LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF CARCINOMA IN ONE (1) LYMPH NODE.

PART 6:

DISTAL URETERAL MARGIN, RIGHT, EXCISION -

NO EVIDENCE OF CARCINOMA.

PART 7:

DISTAL URETERAL MARGIN, LEFT, EXCISION -

NO EVIDENCE OF CARCINOMA.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE:

Other: Hysterectomy & Salpingo-oophorectomy

TUMOR SITE:

Trigone; Right lateral wall, Left lateral wall

TUMOR SIZE:

Greatest dimension: 3.5 cm

Additional dimensions: 3.5 x 1 cm

HISTOLOGIC TYPE:

Urothelial (transitional cell) carcinoma

ASSOCIATED EPITHELIAL LESIONS: None identified

HISTOLOGIC GRADE:

Urothelial carcinoma - High-grade

TUMOR CONFIGURATION:

Ulcerated

PATHOLOGIC STAGING (pTNM):

pT3a

pN0

Number of nodes examined: 8

pMX

MARGINS:

Margins uninvolved by invasive carcinoma

Distance of tumor from closest margin: 5 mm

Margin: Anterior

VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L):

Absent

DIRECT EXTENSION OF INVASIVE TUMOR: None identified

ADDITIONAL PATHOLOGIC FINDINGS:

Cystitis cystica glandularis

Other: Extensive squamous metaplasia

Source: NCI Genomic Data Commons file 4ff54a32-12fb-4f66-8c98-ca684045159c (TCGA-BT-A20U.F1C2F8C6-C3F6-4E69-90FE-E55A44571779.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).